Surgical pathology report (de-identified scan), TCGA case TCGA-AH-6903, project TCGA-READ (Rectum Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AH-6903-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

Histopathological Examination

Path#: [REDACTED]

Pre-Op Diagnosis : Colon Cancer
Order Physician : [REDACTED]
Specimens : Lymph Node, Left Iliac
Colon Segment, rectal sigmoid junction
Anastamotic Rings

Frozen Diagnosis :

Report : GROSS EXAMINATION:

A. The specimen is received fresh labeled with the name of the patient and identified as colon segment, rectosigmoid junction.

Length: 19 cm

Circumference: 6.5 cm

Margins: Stapled closed

Serosa: Smooth

Mass:

Size: 3.5 x 3.2 x 1.2 cm

Type: Polypoid centrally ulcerated

Region: Rectosigmoid

Distance from Mucosal Margin: 4.5 cm, undesignated

Circumference: Approximately 65%

Perforation: No

Mesorectum: N/A (Serosa present the entire length of specimen)

Depth of Invasion: Grossly involves the wall

Distance from Radial Margin: 7 cm

Block Summary: Margins, 1-2; radial margin, 3; mass, 4-9; random colon, 10. All potential lymph nodes are submitted as follows: four potential nodes each, 11-12; five potential nodes each, 13-14.

B. The specimen is received in formalin labeled with the name of the patient and labeled as lymph node, left iliac. The specimen consists of a piece of red-tan soft tissue, which measures 0.8 x 0.6 x 0.4 cm. The specimen is bisected and totally submitted in one block.

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #: [REDACTED]
Visit #: [REDACTED]

Page 1 of 3

[page 2 of 3]
C. The specimen is received in formalin labeled with the name of the patient and identified as anastomotic rings. Received are two complete segments of colon tissue measuring 1.9 cm and 2.4 cm in greatest dimension. Representative section of each is submitted in one block. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

A. Colon, rectosigmoid, resection:

- Invasive adenocarcinoma, moderately differentiated, with invasion through muscularis propria into subserosal tissue.
- Metastatic adenocarcinoma in 3 of 17 lymph nodes (3/17).
- See cancer case summary checklist.
- [T-59600 M-81403 154.1 P3-44090]

B. Lymph node, left iliac, biopsy:

- One benign lymph node, negative for metastatic carcinoma (0/1).
- See cancer case summary checklist.
- [T-C4000 M-09470 V71.1 P3-44050]

C. Anastomotic rings, excision:

- Colonic wall with no significant pathologic alteration.
- No malignancy identified.
- [T-59000 M-00110 V71.9 P3-44040]

CANCER CASE SUMMARY CHECKLIST

SPECIMEN: Sigmoid colon and rectum

PROCEDURE: Low anterior resection (per operative report)

SPECIMEN LENGTH: 19 cm

TUMOR SITE: Rectosigmoid

TUMOR SIZE: 3.5 cm in greatest dimension

MACROSCOPIC TUMOR PERFORATION: Not grossly identified.

MACROSCOPIC INTACTNESS OF MESORECTUM: Not applicable (Serosa present the entire length of specimen).

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: Low-grade (moderately differentiated)

MICROSCOPIC TUMOR EXTENSION: Tumor invades through the muscularis propria into the subserosal adipose tissue.

MARGINS:

- Proximal margin uninvolved by invasive carcinoma.
- Distal margin uninvolved by invasive carcinoma.
- Radial margin uninvolved by invasive carcinoma.
- Distance of invasive carcinoma from closest margin equals 4.5 cm (undesignated mucosal margin)

TREATMENT EFFECT: No known prior treatment

LYMPH-VASCULAR INVASION: Not identified.

PERINEURAL INVASION: Not identified.

TUMOR DEPOSITS: Not identified.

TYPE OF POLYP IN WHICH INVASIVE CARCINOMA AROSE: Villous adenoma

PATHOLOGIC STAGING (pTNM):

- Primary Tumor (pT): pT3 (tumor invades through the muscularis propria into the pericorectal tissues)
- Regional Lymph Nodes (pN): pN1b (metastasis in 2 to 3 regional lymph nodes)

Number examined: 18

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[page 3 of 3]
Number involved: 3
- Distant Metastasis (pM): Not applicable.

Intradepartmental consultation obtained.

[REDACTED]

Electronically Signed by:

[REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path
Visit

[REDACTED]

Page 3 of 3

Source: NCI Genomic Data Commons file 418349cf-b509-4027-9546-cb2f6defc373 (TCGA-AH-6903.0343A949-BF7A-432E-A06A-B481717B226E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).